TCGA case TCGA-DX-A8BU — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Fibromatous Neoplasms; Primary site: Connective, subcutaneous and other soft tissues; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4996e458-db04-4c6d-9ae6-66316240a8ed

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: United States; Age at index: 58 years; Vital status: Dead; Days to death: 1,116 days (3.1 years).

Diagnoses (6)
1. Malignant fibrous histiocytoma (the primary disease): ICD-O-3 morphology code: 8830/3; ICD-10 code: C49.2; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Site of resection or biopsy: Connective, subcutaneous and other soft tissues of lower limb and hip; Classification of tumor: primary; Age at diagnosis: 58.8 years (21,470 days); Year of diagnosis: 2006; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Sites of involvement: Lung, NOS; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 7.9; Tumor length measurement: 12.4; Tumor width measurement: 8.4.
   Pathology details: Consistent pathology review: Yes; Margin status: Involved; Necrosis percent: 30; Necrosis present: Yes; Tumor depth descriptor: Deep.
2. Metastasis of diagnosis 1 (Malignant fibrous histiocytoma), site: Lung, NOS. Age at diagnosis: 59.1 years (21,577 days); Days to diagnosis: 107 days; Prior treatment: Yes.
3. Metastasis of diagnosis 1 (Malignant fibrous histiocytoma), site: Vertebral column. Age at diagnosis: 60.2 years (21,997 days); Days to diagnosis: 527 days (1.4 years); Prior treatment: Yes.
4. Metastasis of diagnosis 1 (Malignant fibrous histiocytoma), site: Pancreas, NOS. Age at diagnosis: 61.6 years (22,505 days); Days to diagnosis: 1,035 days (2.8 years); Prior treatment: Yes.
5. Metastasis of diagnosis 1 (Malignant fibrous histiocytoma), site: Rib, sternum, clavicle and associated joints. Age at diagnosis: 61.6 years (22,505 days); Days to diagnosis: 1,035 days (2.8 years); Prior treatment: Yes.
6. Metastasis of diagnosis 1 (Malignant fibrous histiocytoma), site: Spleen. Age at diagnosis: 61.6 years (22,505 days); Days to diagnosis: 1,035 days (2.8 years); Prior treatment: Yes.

Follow-up (6 entries)
- Day 107 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 107 days.
- Day 527 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Vertebral column; Days to progression: 527 days (1.4 years).
- Day 1,035 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Spleen; Days to progression: 1,035 days (2.8 years).
- Day 1,035 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Rib, sternum, clavicle and associated joints; Days to progression: 1,035 days (2.8 years).
- Day 1,035 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Pancreas, NOS; Days to progression: 1,035 days (2.8 years).
- Days to follow up: 1,116 days (3.1 years); Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DX-A8BU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 780 mg.
  Slide TCGA-DX-A8BU-01A-01-TSA: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 19; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 1.
- Sample TCGA-DX-A8BU-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DX-A8BU-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology: Histologic diagnosis: Pleomorphic 'MFH' / Undifferentiated pleomorphic sarcoma; Margin status: Positive; Tumor total necrosis: Moderate Necrosis (>=10, <50%); Disease multifocal indicator: No; Locoregional recurrence indicator: No; Metastatic disease confirmed: Yes; Metastasis site: Lung.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Lower Extremity - Thigh/knee.
- Drug treatment 1: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 1080; Days from index date to pharmaceutical treatment ended: 1081; Pharmaceutical therapy drug name: Ifosfamide; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment 1, Therapy types: Pharmaceutical therapy type: Chemotherapy.
- Drug treatment 2: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 678; Pharmaceutical therapy drug name: Docetaxel; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment 3: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 678; Pharmaceutical therapy drug name: Gemcitabine; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment 4: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 590; Days from index date to pharmaceutical treatment ended: 647; Pharmaceutical therapy drug name: Doxil; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment 5: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 123; Days from index date to pharmaceutical treatment ended: 228; Pharmaceutical therapy drug name: Adriamycin; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment 6: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 123; Days from index date to pharmaceutical treatment ended: 228; Pharmaceutical therapy drug name: Ifosfamide; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Radiation treatment: Days from index date to radiation therapy started: 52; Days from index date to radiation therapy ended: 100; Radiation therapy type: External; Radiation total dose: 6300; Radiation adjuvant units: cGy; Radiation adjuvant fractions total: 35; Radiation therapy site: Primary Tumor Field; Radiation therapy ongoing indicator: No; Treatment best response: Radiographic Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,116 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,116 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 107 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DX-A8BU-01A-11D-A37B-01): tumor purity 0.93, ploidy 1.73, whole-genome doublings 0.
